Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A7TC, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A7TC-01A (Primary Tumor).

[page 1 of 2]
ICD O3
Astrocytoma, grade II 9400/3
Site: Brain, supratentorial NOS
path C71.0
Brain NOS C71.9
4/22/14

Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age:) Location: Received:

Gender: M Acct: Reported:

Physician(s):

Phy Location:

Clinical History

Probably low grade gliomas

Operative Diagnoses

Operation / Specimen

A: Brain, probably tumor, biopsy

Pathologic Diagnosis

A. Brain, tumor, excision biopsy: Diffuse astrocytoma, WHO grade II (see comment).

Comment

Permanent sections confirm the frozen section diagnosis. Sections show an infiltrating astrocytoma.

Mitotic figures

and/or vascular proliferation are not seen. The Ki-67 labeling index is approximately 3%. Positive and negative

controls show appropriate immunoreactivity.

Additional studies will be reported below in procedure addenda.

Electronically Signed Out

, Senior Staff Pathologist

Resident Pathologist

Consultant: , Senior Staff Pathologist

Procedures/Addenda

MGMT Promoter Methylation

Date Ordered: Date Reported:

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A2)

H and E slide was examined and tumor DNA was enriched by microdissection

Surgical Pathology

Page 2 of 3

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

[page 2 of 2]
was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

.. Senior Staff Pathologist

Consultant:

Intra-Operative Consultation

A. Brain, tumor, biopsy: Infiltrating glioma (favor low-grade astrocytoma). Frozen section and smears performed at

and results reported to the Physician of Record.

Senior Staff Pathologist

Gross Description

A. Brain, tumor, biopsy:

FIXATIVE: None, delivered fresh.

DESCRIPTION: Fragments of brain tissue measuring 1 to 0.3 cm in largest dimension. Distinct white and gray matter

is seen. Also, there are tan-gray gelatinous areas suspicious for glial neoplasm. Imprint slides, smears, and frozen

section were performed.

SLIDES: A1: frozen section remnants; A2-3: rest of the tissue, entirely submitted.

Resident Pathologist

ICD-9(s): 191.2 191.2

Billing Fee Code(s): A:

MGMT:

Histo Data

Part A: Brain, probably tumor, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

FS H&E x 1 1

H&E x 1 1

TPS H&E x 1 1

H&E x 1 2

MGMT-slides x 1 2

Surgical Pathology

Page 3 of 3

MIB1-DA x 1 2

Please also run the IDH1 antib

Rct 1 H&E x 1 2

H&E x 1 3

Source: NCI Genomic Data Commons file 6a587fed-1844-476e-a89c-ad7289a0f5c3 (TCGA-DU-A7TC.A2300731-ACA8-4F35-ADA4-49D10D4CE389.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).